TCGA case TCGA-BR-8370 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cae32f61-6b84-4122-af33-d8cbf410d4c8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Ukraine; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.0; Tissue or organ of origin: Cardia, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 64.7 years (23,636 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N3a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 101 days.
   Pathology details: Consistent pathology review: No; Lymph nodes positive: 9; Lymph nodes tested: 15.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Oxaliplatin; Days to treatment start: 34 days; Days to treatment end: 101 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Days to treatment start: 34 days; Days to treatment end: 101 days; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 17 days; Disease response: Tumor Free.
- Days to follow up: 101 days; Disease response: Tumor Free.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BR-8370-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 1.5; Shortest dimension: 0.6.
  Slide TCGA-BR-8370-01A-01-TS1: Section location: Top; Percent tumor cells: 74; Percent tumor nuclei: 75; Percent normal cells: 3; Percent necrosis: 8; Percent stromal cells: 15.
  Slide TCGA-BR-8370-01A-01-BS1: Section location: Bottom; Percent tumor cells: 72; Percent tumor nuclei: 80; Percent normal cells: 8; Percent necrosis: 5; Percent stromal cells: 15.
- Sample TCGA-BR-8370-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BR-8370-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Diffuse Type; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Cardia/Proximal; Lymph nodes examined: Yes; Cancer procurement city: Kiev.
- Drug treatment 1: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Follow-up form: Lost to follow-up: Yes; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 101 days; disease-specific survival: no event (censored), 101 days; disease-free interval: no event (censored), 101 days; progression-free interval: no event (censored), 101 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BR-8370-01A-11D-2338-01): tumor purity 0.96, ploidy 2.17, whole-genome doublings 0.
